Somatic mutation profile of tumor specimen BA2840D (aliquot aq-BA2840D) from BEATAML1.0 case 2468, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.8 years (28,766 days).
Specimen BA2840D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7225af36-0ab7-49be-80a3-e742eef910e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2783D (Solid Tissue Normal), aliquot aq-BA2783D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b607cda-0c52-4e3e-9dc9-9237076b35b7

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLEC1 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57306534; called by muse, mutect2
- POLE | c.4720G>A p.A1574T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs878854876; ClinVar: uncertain significance; called by muse, mutect2
- TRIM69 | c.943C>A p.Q315K (on ENST00000329464 / NM_182985.5; = p.Q156K on NM_080745.5) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145552604; called by muse, mutect2
- ZNF630 | c.968A>T p.K323M | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV99332216; called by mutect2, varscan2
- ADAM29 | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2
- KCNC1 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAAR9 | c.1008A>C p.S336= | Silent (SNP) | VAF 43/152 reads (28%) | called by muse, mutect2, varscan2
- AC068587.7 | chr8:12659508 del CTCTGGCGCC | 5'Flank (DEL) | VAF 9/65 reads (14%) | catalogued as rs759659289; called by mutect2, pindel
- SLC9A8 | c.-88C>A | 5'UTR (SNP) | VAF 3/46 reads (7%) | catalogued as rs1271221689; called by muse, mutect2
